Somatic mutation profile of tumor specimen 0DJO5D from CCDI case PBBWRM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 7.2 years (2,622 days).
Specimen 0DJO5D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 115babd6-9666-4a15-b9d1-72c9e1a188ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d60c75a5-211d-40b6-aa37-fb145812a325

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FHL5 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 56/1302 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV100459414; called by muse, mutect2
- ZNF479 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100482620; called by mutect2, varscan2
- CEP112 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 71/568 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KDM2A | c.3193C>G p.L1065V | Missense Mutation (SNP) | VAF 30/608 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.262); called by muse, mutect2
- SLC6A11 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- KCNJ6 | c.612C>A p.V204= | Silent (SNP) | VAF 26/569 reads (5%) | catalogued as COSV55713675; called by muse, mutect2
- MYLK | c.3900G>A p.A1300= | Silent (SNP) | VAF 482/1035 reads (47%) | catalogued as rs563116446, COSV60613110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG7 | c.1293-77G>A | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
